Somatic mutation profile of tumor specimen TARGET-10-PARLDF-09A (aliquot TARGET-10-PARLDF-09A-01D) from TARGET case TARGET-10-PARLDF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,512 days).
Specimen TARGET-10-PARLDF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) facfc572-8254-4289-a982-248f117598b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLDF-10A (Blood Derived Normal), aliquot TARGET-10-PARLDF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f260ddb3-a6b1-4e94-9ae1-d78793f7faf2

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.728A>T p.H243L (on ENST00000611781; = p.H187L on NM_052997.2) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV64618228; called by muse, mutect2, varscan2
- C14orf93 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1197592731; called by muse, mutect2, varscan2
- CACNG4 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1466892036, COSV50924354, COSV50925321; called by muse, mutect2
- CALB1 | c.507-1G>C p.X169_splice | Splice Site (SNP) | VAF 10/17 reads (59%) | catalogued as rs1439304159; called by muse, mutect2, varscan2
- KCNT1 | c.686C>T p.A229V (on ENST00000488444; = p.A248V on NM_020822.3) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs575954363; called by muse, mutect2, varscan2
- LAMC3 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750461310, COSV100736144; called by muse, mutect2, varscan2
- OGDHL | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs760518509, COSV65102202; called by muse, mutect2, varscan2
- PCDHGB1 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs747653356; called by muse, mutect2, varscan2
- SEC24A | c.1363T>C p.C455R | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs555566478; called by muse, mutect2, varscan2
- TSPAN13 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as rs892001134; called by muse, mutect2
- ZNF765 | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as COSV67182982; called by muse, mutect2, varscan2
- ALPK2 | c.4700T>C p.V1567A | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DHRS13 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506994 del TGTAT | Missense Mutation (DEL) | VAF 9/17 reads (53%) | called by pindel*, varscan2
- SYNPO2 | c.3594G>T p.E1198D | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF99 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2
- ENKUR | c.459C>T p.V153= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- LRFN2 | c.390C>T p.I130= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as COSV57827700, COSV57829989; called by muse, mutect2, varscan2
- MANSC4 | c.180T>C p.S60= | Silent (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- TRIM22 | c.303A>G p.G101= | Silent (SNP) | VAF 53/100 reads (53%) | called by muse, mutect2, varscan2
